Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A25R, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A25R-01A (Primary Tumor).

[page 1 of 2]
Concurrent/Synchronous Primary Tumor	☒	☐

FINAL DIAGNOSIS -----

THYROID AND CENTRAL NECK (TOTAL THYROIDECTOMY AND DISSECTION):

SPECIMEN TYPE:

Total thyroidectomy

1C8-0-3

TUMOR SITE:

Isthmus

(Path) Carcinoma, papillary, thyroid 8260/3

HISTOLOGIC TYPE:

Papillary carcinoma

(CQCF) Carcinoma, papillary, tall cell 8344/3

Site: thyroid, NOS C73.9

TUMOR SIZE:

Greatest dimension: 2.6 cm

fw
6/2/11

FOCALITY:

Unifocal

LYMPH NODES:

None submitted

EXTENT OF INVASION

PRIMARY TUMOR:

pT3: Tumor with minimal extrathyroidal extension. see note

REGIONAL LYMPH NODES:

pNx: cannot be assessed

MARGINS:

Margins are uninvolved

VENOUS/LYMPHATIC INVASION:

Indeterminate

ADDITIONAL PATHOLOGIC FINDINGS:

Parathyroid tissue seen in soft tissue attached to the inferior portion of the thyroid.

NOTE: This case was shown at the

[page 2 of 2]
PART #1: TOTAL THYROID AND CENTRAL NECK

Dictated:

The specimen is received fresh, labeled with the patient's name, xxxx, and designated 'Total Thyroid and Central Neck.' The specimen consists of a complete intact thyroid weighing 18.3 grams and measures 8.0 x 4.0 x 0.8 cm in total. The specimen has been oriented with a stitch to indicate the tumor nodule. The posterior surface is inked black and the anterior surface orange. The specimen is serially sectioned from superior to inferior to reveal a tan nodule with infiltrative borders and cystic areas that measure 2.6 x 1.6 x 1.1 cm located in the isthmus lobe. The nodule grossly abuts the posterior margin. Sectioning through the remainder of the right and left lobes does not reveal any other grossly identifiable nodules. The right lobe measures 3.6 x 2.1 x 0.8 cm and the left 2.0 x 2.1 x 0.5 cm. The isthmus measures 3.0 x 1.5 x 1.4 cm. The thyroid specimen also comes with a small central neck dissection measuring 1.5 x 0.3 x 0.3 cm. The soft tissue is submitted in its entirety, although no grossly identifiable lymph nodes are seen. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS:

- 4 - A-D - 2 EA (SECTIONING FROM SUPERIOR TO INFERIOR, LEFT LOBE)
- 5 - E-I - 2 EA (SECTIONING FROM SUPERIOR ISTHMUS LOBE TO INFERIOR ISTHMUS LOBE)
- 1 - J - 2 (SUPERIOR RIGHT LOBE)
- 7 - K-Q - 1 EA (SECTIONING FROM SUPERIOR RIGHT LOBE TO INFERIOR RIGHT LOBE)
- 2 - R,S - 2 EA (INFERIOR RIGHT LOBE)
- 2 - T,U - M EA (CENTRAL NECK DISSECTION)
- 21 - TOTAL - MULTIPLE

Source: NCI Genomic Data Commons file 2f6afef5-0a01-4845-bc44-8ac4780af9a5 (TCGA-ET-A25R.E55B4BC8-6271-4992-9529-D5B173D18486.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).